Surgical pathology report (de-identified scan), TCGA case TCGA-66-2737, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2737-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right middle lobe, among others

Clinical diagnosis and question

Bronchial carcinoma right middle lobe, status post NHL right cervical

REPORT ON FINDINGS**Macroscopy**

- 1.) Hilar LN (station 10) right: 2.5 cm fatty specimen with 2 nodes, 2.5 and 1.2 cm, section surface of larger grayish-black and of smaller pale reddish node with 5 mm whitish focus.
- 1.) Right middle lobe: inflated, fixed bilobectomy preparation measuring 18 x 16 cm, up to 17 cm high. Central bronchus resection plane located 1 cm proximal to the division into the lobe bronchi. At the hilus two black nodes, 1.2 cm and 0.9 cm in size. Dorsal to the intermediate bronchus a staple suture line runs 7.5 cm in a cranial direction to the apex of the lower lobe, and a second staple suture line runs 10 cm from the hilus along the cranial margin of the middle lobe. Lateral pleura over S4 shows a star-shaped area of retraction measuring 2.5 cm, with a pale brown discoloration in the marginal region, under this a tumor, max. 6.5 cm in size, with a polycyclic demarcation, obstructing the middle lobe bronchus in the proximal sections and extending to within 1.5 cm of the bronchus resection margin. Spread to the pleura in the area of its retraction, section surfaces pale brown to gray, partly with blackish pigmentation. Mucosa in the region of the ostium of the middle lobe bronchus and the adjoining intermediate bronchus extending irregularly to the resection margin. Lung parenchyma of remaining middle lobe and lower lobe inconspicuous.
- 3.) Bronchial sleeve: 2 cm segment of bronchus with 2 cm resection margin to the main bronchus (line marked) and 1.1 cm resection margin to the upper lobe bronchus. Distal end closed by metal staple suture.
- 4.) Upper and middle lobes: two 2 cm irregular black nodes or node parts.
- 5.) Lobar LN (station 12) right: 1 cm node.
- 6.) Hilar LN (station 10) right: 8 mm node with surrounding tissue.
- 7.) Pulmonary ligament LN (station 9) right: three node between 0.5 and 1 cm with surrounding tissue
- 8.) Prevascular and retrotracheal LN (station 3) right:

Examined:

- 1.) Rapid section remains and 1 further section each,
- 2.) Bronchus resection margin tangential and rapid section remains, 2 sections middle lobe bronchus proximal to tumor obstruction, 1 section of tumor middle lobe bronchus closure and parabronchial lymph nodes, 2 sections of tumor with pleura, 1 section S5, 1 section S10, vessel resection margins and nodes,
- 3.) Resection margin to main bronchus tangential, resection margin to upper lobe bronchus tangential, cross-section close to distal resection margin,
- 4.) - 7.) All material (in 4. - 6. halved in each case),
- 15 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

[page 2 of 2]
Microscopy

Re 1.) Immediate intraoperative evaluation (): metastasis of squamous cell carcinoma.

After paraffin embedding.

Lymph node sections with extensive infiltration by atypical epithelia arranged in differing sizes of partly branched and vaguely epidermoid or concentrically layered solid structures. Moderately wide to wide, pale to moderately eosinophilic cytoplasm. Focally recognizable intercellular bridges. Nuclei round to oval, partly with somewhat irregular contours, mostly moderately, but focally also markedly anisomorphic, with enlarged chromatin, differing sizes of nucleoli and numerous mitoses. Surrounding desmoplastic stroma. Small focal inclusion of necrosis.

Re 2.) Immediate intraoperative evaluation (): squamous cell dysplasia up to severity of a squamous cell carcinoma in situ with spread to bronchial glands, no evidence of invasive growth rapid sections.

After paraffin embedding.

Tumor made up of atypical epithelia described in 1.). Focal dyskeratoses or vague pearly bead formation. Isolated nuclei also deformed. Multifocal necroses of differing extent. Middle lobe bronchus segmentally obstructed by the tumor and in large parts destroyed, here continuous infiltration of parabronchial lymph nodes. Spread to the visceral pleura, which is markedly enlarged by fibrosis in parts, but not unequivocally infiltrated. In many places invasion of small blood vessels in the tumor and tumor margin. Proximal to the tumor obstruction in the middle lobe bronchus and also at the bronchus resection margin partial replacement of the respiratory epithelium by enlarged atypical squamous epithelium extending to the secretory ducts and bronchial glands with the squamous disorder mostly reaching well into the upper third or to the surface. Nuclei irregularly arranged, in most cases slightly to moderately anisomorphic, but with foci of relatively marked anisomorphism, and formation here and there of keratin lamellae and pearly beads. Vessel resection margins and hilar lymph nodes tumor-free. In S5 incompletely inflated alveolar lung tissue in parts with relatively extensive intraalveolar erythrocyte extravasates.

Otherwise in many places the alveolar lumina and partly also the lumina of bronchioles are occupied with moderately dense macrophages, some transformed into foam cells, some pale brown and with fine granular blackish pigmentation. In multifocal parabronchial vessels and in interlobular septa lymph follicles and small patches of relatively dense lymphomonocytic infiltrates. In S10 mostly only a few intraalveolar macrophages.

Re 3.) Immediate intraoperative evaluation () resection margin to main bronchus + upper lobe bronchus in each case tumor-free and free of dysplastic epithelial lesions.

After paraffin embedding:

Bronchial sections with focal replacement of respiratory epithelium by immature squamous epithelium at the margin to the main and upper lobe bronchus. Stroma with increase in elastic fibers. To some extent somewhat prominent seromucous glands. Strands of typical hyaline cartilage. Close to the distal resection margin only sections of atypical squamous epithelium preserved or registered at the surface as described under 2.), here likewise focal spread in glandular ducts.

Re 4.) - 7.) Lymph nodes with intact basic structure, inconspicuous lymphatic cell content with formation of activated follicles and slight to moderate deposits of blackish granular pigment and some small anisotropic particles within macrophages.

EVALUATION

Primary diagnosis/diagnoses: relatively large, central to peripheral bronchopulmonary, histologically moderately differentiated, large-cell, slightly keratinizing squamous cell carcinoma of the middle lobe.

TNM classification pT2 pN1. V1 R0, stage IIB.

C 34.2 M 8070/3

Secondary diagnosis/diagnoses: slight chronic retention pneumonia peripheral to the tumor in S5. Lymph nodes with uncharacteristic reactive lesions and anthracotic pigment deposits (samples 2.) and 4.) - 7.).

Remark/addendum: the tumor shows obliterative segmental growth in the middle lobe bronchus and has spread to the mucosal surface right to the central bronchus resection line of sample 2.) and to the distal sections of repeat bronchial resection material in sample 3.). The resection margin to the main and upper lobe bronchus of sample 3.) is free of dysplastic epithelial changes. Lymph node metastases are seen in sample 1.) and parabronchially in sample 2.). The other lymph nodes removed and the vessel resection margins of the main preparation are tumor-free. An unequivocal infiltration of the visceral pleura cannot be demonstrated.

Source: NCI Genomic Data Commons file dc51c0c5-a467-4037-8b3f-923235b93e85 (TCGA-66-2737.81CC3E56-576F-4285-906C-75290F9AE4B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).